Surgical pathology report (de-identified scan), TCGA case TCGA-B0-4834, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-4834-01A (Primary Tumor).

FINAL DIAGNOSIS

KIDNEY, RIGHT, RADICAL NEPHRECTOMY:

- A. RENAL CELL CARCINOMA, EOSINOPHILIC VARIANT OF CONVENTIONAL CLEAR CELL TYPE.
- B. FUHRMAN'S NUCLEAR GRADE III OF IV.
- C. THE GREATEST DIAMETER OF THE NEOPLASM IS 4.0 CM.
- D. THE NEOPLASM IS CONFINED WITHIN THE RENAL CAPSULE.
- E. NO INVASION OF THE RENAL VEIN IS IDENTIFIED.
- F. NO EVIDENCE OF ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- G. ALL SURGICAL MARGINS ARE FREE OF THE NEOPLASM.
- H. THE NON-NEOPLASTIC KIDNEY REVEALS HYALINE ARTERIOLOSCLEROSIS. NO INTERSTITIAL FIBROSIS OR GLOMERULOSCLEROSIS IS SEEN.
- I. AN ORGANIZING HEMATOMA IS SEEN IN THE SUBCAPSULAR REGION.
- J. TNM STAGE: pT1a Nx Mx.
- K. TNM HISTOLOGIC GRADE = G3.

Source: NCI Genomic Data Commons file b79fb353-b738-438f-8868-d9b5d09fd6af (TCGA-B0-4834.12C56AF3-B9FF-4263-B41F-552DD96FA093.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).